Somatic mutation profile of cancer-model specimen HCM-SANG-0296-C15-85A (3D Organoid; aliquot HCM-SANG-0296-C15-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-SANG-0296-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0296-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 185833cf-16f0-48fc-abca-25d207dafaa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0296-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0296-C15-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b39fad-9158-4830-9608-dd1ea97b9a18

The open-access MAF lists 235 somatic variants for this specimen: 159 protein-altering or splice-affecting, 47 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 47, RNA 9, 5'UTR 7, Splice Region 7, Intron 6, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 4, 5'Flank 3, 3'UTR 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 98/99 reads (99%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.3352C>T p.R1118W (on ENST00000372530 / NM_001198934.2; = p.R1090W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773849977; called by muse, mutect2, varscan2
- ADORA2A | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 157/301 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199999926; called by muse, mutect2, varscan2
- AKAP8L | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs748251479, COSV68472898; called by muse, mutect2, varscan2
- ALOX5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 127/266 reads (48%) | SIFT tolerated (0.96); PolyPhen benign (0.052); catalogued as rs1378362151, COSV100980184; called by muse, mutect2, varscan2
- AQR | c.3425+7G>A | Splice Region (SNP) | VAF 49/140 reads (35%) | catalogued as rs1340052608; called by muse, mutect2, varscan2
- ARHGEF7 | c.1606C>G p.L536V (on ENST00000375741 / NM_001113511.2; = p.L358V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV54545289; called by muse, mutect2
- ASPHD2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1196955543; called by muse, mutect2
- BCL2L13 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs766203253, COSV58226582; called by muse, mutect2, varscan2
- CACNA1A | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761827501, COSV64206594; called by muse, mutect2, varscan2
- CCDC80 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 50/461 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1388319525, COSV52815430; called by muse, varscan2
- CDH13 | c.2028G>T p.R676S | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99224179, COSV99224502; called by muse, mutect2
- CHRNA7 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1363848054; called by mutect2, varscan2
- COL17A1 | c.2658G>T p.L886F | Missense Mutation (SNP) | VAF 188/192 reads (98%) | SIFT tolerated (0.72); PolyPhen benign (0.088); catalogued as rs758172974; called by muse, mutect2, varscan2
- COL20A1 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 143/411 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as rs760604465, COSV104401076; called by muse, mutect2, varscan2
- COL6A3 | c.7610G>A p.G2537E | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55095606; called by muse, mutect2, varscan2
- CRACR2A | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV52912844; called by muse, mutect2
- D2HGDH | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 165/285 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs754696671, COSV58319555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.9557C>T p.A3186V | Missense Mutation (SNP) | VAF 244/570 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747233018, COSV67750093; called by muse, mutect2, varscan2
- DNAH3 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.934); catalogued as rs754186361, COSV54507193; called by muse, mutect2, varscan2
- EBF4 | c.1565C>T p.A522V (on ENST00000609451; = p.A518V on NM_001110514.1) | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); catalogued as rs749340560, COSV61355860; called by muse, varscan2
- FLOT1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs757846029; called by muse, mutect2, varscan2
- GRIK3 | c.2702G>A p.R901Q | Missense Mutation (SNP) | VAF 94/95 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as rs138171690; called by muse, mutect2, varscan2
- GRM3 | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64469170; called by muse, mutect2, varscan2
- IMPACT | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 54/54 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs753777036, COSV52421166; called by muse, mutect2
- INTS6L | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100878337; called by muse, mutect2, varscan2
- IQGAP1 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs1409133844; called by muse, mutect2
- IREB2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs1489766318; called by muse, mutect2, varscan2
- IRS4 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 382/383 reads (100%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs928579393, COSV100929534; called by muse, mutect2, varscan2
- KCNH2 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 327/331 reads (99%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199472901, CM993712, COSV100060568; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- KIAA0586 | c.1483C>T p.R495C (on ENST00000619416 / NM_001244190.2; = p.R510C on NM_014749.5) | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778123212, COSV54175650; called by muse, mutect2, varscan2
- KMT2D | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768072508, COSV56437118; called by muse, mutect2, varscan2
- KRT73 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 68/115 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs138468964, COSV59838883, COSV99988265; called by muse, mutect2, varscan2
- KRTAP10-7 | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 17/452 reads (4%) | catalogued as rs782489979; called by muse, mutect2
- L1CAM | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 215/217 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1557091785, COSV62827843, COSV62828577; called by muse, mutect2, varscan2
- LEFTY2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs773437742, COSV64747643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBP2 | c.4297C>T p.R1433C (on ENST00000357337; = p.R1471C on NM_015057.5) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1383535643, COSV62017602; called by muse, mutect2
- MYH3 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs753191024, COSV56867498; called by muse, mutect2, varscan2
- NTRK3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs758189455, COSV58115768, COSV58130494, COSV58148431; called by muse, mutect2
- OLFM1 | c.1099G>A p.V367M (on ENST00000371793 / NM_001282611.2; = p.V349M on NM_014279.5) | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs950757823, COSV99423363; called by muse, mutect2, varscan2
- OR4C13 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.013); catalogued as rs1555015795; called by muse, mutect2, varscan2
- PLXNB2 | c.2969C>G p.P990R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63781140, COSV63783501; called by muse, mutect2
- RASGRF1 | c.2342G>C p.G781A | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.953); catalogued as COSV67251073; called by muse, mutect2
- SCARA5 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 115/183 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs374361225; called by muse, mutect2, varscan2
- SDSL | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.001); catalogued as rs144641930; called by muse, mutect2, varscan2
- SERPINI2 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV52987841; called by muse, mutect2, varscan2
- SEZ6L2 | c.2206G>T p.G736W (on ENST00000308713 / NM_001114099.3; = p.G666W on NM_012410.4) | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435405; called by muse, mutect2
- SLC7A14 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 440/735 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51585398; called by muse, mutect2, varscan2
- SMAD4 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV61687777; called by muse, mutect2, varscan2
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 50/64 reads (78%) | catalogued as rs747624971; called by mutect2, varscan2
- SP7 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs1396601312; called by muse, mutect2, varscan2
- TET1 | c.2331C>A p.F777L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV65383087; called by muse, mutect2, varscan2
- TGM2 | c.435G>A p.A145= | Splice Region (SNP) | VAF 103/532 reads (19%) | catalogued as rs200446060, COSV63931501; ClinVar: benign; called by muse, mutect2, varscan2
- TRAP1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as rs141984778; called by muse, mutect2, varscan2
- TTN | c.70691C>T p.P23564L (on ENST00000591111; = p.P16140L on NM_003319.4) | Missense Mutation (SNP) | VAF 97/224 reads (43%) | PolyPhen probably damaging (0.999); catalogued as rs1324051113; called by muse, mutect2, varscan2
- TTN | c.39892+1G>A p.X13298_splice (on ENST00000591111; = p.X5874_splice on NM_003319.4) | Splice Site (SNP) | VAF 57/211 reads (27%) | catalogued as COSV60201655; called by muse, mutect2, varscan2
- TTN | c.32705C>T p.P10902L (on ENST00000591111; = p.P9975L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/215 reads (39%) | PolyPhen benign (0.154); catalogued as rs757268986, COSV59976511, COSV60422857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT9B | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); catalogued as rs147655057; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV54298314, COSV99648331; called by muse, mutect2, varscan2
- ZNF213 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 181/369 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs374127420, COSV67727974; called by muse, mutect2, varscan2
- ADGB | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- ADGRF4 | c.1643C>A p.A548D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AGBL5 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMOT | c.2995G>C p.A999P (on ENST00000371959 / NM_001113490.1; = p.A590P on NM_133265.3) | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP23 | c.3695del p.P1232Rfs*51 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP24 | c.1977_1999del p.I660Efs*18 (on ENST00000395184 / NM_001025616.3; = p.I567Efs*18 on NM_031305.3) | Frame Shift Del (DEL) | VAF 44/56 reads (79%) | called by mutect2, pindel, varscan2
- ASB3 | c.1548A>T p.Q516H | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- C16orf95 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1A | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.56); called by muse, mutect2
- CAD | c.6034C>A p.Q2012K | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CATSPERG | c.948_950del p.Y317del | In Frame Del (DEL) | VAF 445/774 reads (57%) | called by pindel, varscan2
- CCDC27 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 97/98 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CEP250 | c.5704G>T p.A1902S | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CFH | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2
- CR1L | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2
- CRIM1 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); called by muse, mutect2
- CXCR2 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DBR1 | c.194_195insAA p.Y65* | Nonsense Mutation (INS) | VAF 126/330 reads (38%) | called by mutect2, varscan2
- DBR1 | c.193delinsGAA p.Y65Efs*44 | Frame Shift Ins (INS) | VAF 80/295 reads (27%) | called by mutect2*, pindel, varscan2*
- DNAH14 | c.4805A>T p.E1602V (on ENST00000445597; = p.E2007V on NM_001367479.1) | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNHD1 | c.7621C>T p.P2541S | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.672); called by muse, mutect2
- DPY19L3 | c.720A>G p.E240= | Splice Region (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- DUOX2 | c.2018A>G p.Q673R | Missense Mutation (SNP) | VAF 26/411 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- DZIP1 | c.37-3C>A | Splice Region (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- E2F7 | c.1694C>G p.P565R | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.083); called by muse, mutect2
- EDNRB | c.1264T>A p.F422I (on ENST00000377211 / NM_001201397.1; = p.F332I on NM_000115.5) | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF2KMT | c.743-1G>A p.X248_splice | Splice Site (SNP) | VAF 157/297 reads (53%) | called by muse, mutect2, varscan2
- EPB41L4B | c.2415G>C p.R805S | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.942); called by muse, mutect2
- FAM47C | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FGF23 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- FKBP15 | c.1811+1G>T p.X604_splice | Splice Site (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- FKBPL | c.860A>T p.K287M | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXD3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- FOXD4L4 | c.415A>G p.S139G | Missense Mutation (SNP) | VAF 59/520 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by mutect2, varscan2
- GIGYF2 | c.1095A>C p.E365D | Missense Mutation (SNP) | VAF 158/295 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8H | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 48/131 reads (37%) | called by mutect2, varscan2
- HEPHL1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 136/184 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- HP1BP3 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.188); called by muse, mutect2
- HS3ST4 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- IFNA4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IGSF9 | c.3143T>C p.L1048P (on ENST00000368094 / NM_001135050.2; = p.L1032P on NM_020789.4) | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IQCA1 | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- JMJD1C | c.5562T>A p.F1854L | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNQ3 | c.2267C>A p.S756Y | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- KIAA2026 | c.4095G>A p.M1365I | Missense Mutation (SNP) | VAF 350/352 reads (99%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21A | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF5C | c.2474G>C p.G825A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KNDC1 | c.4057A>T p.I1353F | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KRTAP10-3 | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- MAST3 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEFV | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 255/521 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP9 | c.264C>G p.S88R | Missense Mutation (SNP) | VAF 245/631 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- MRGPRX2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MUC4 | c.5899A>G p.T1967A | Missense Mutation (SNP) | VAF 87/2493 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.224); called by muse, mutect2
- MYH3 | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- NFRKB | c.584T>C p.V195A (on ENST00000446488 / NM_001143835.2; = p.V208A on NM_006165.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OGDH | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ONECUT1 | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- OR10A6 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 147/148 reads (99%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR4D2 | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 52/770 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2
- PAX1 | c.669C>A p.N223K | Missense Mutation (SNP) | VAF 194/540 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- PIP4K2A | c.66C>G p.H22Q | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PLAC1 | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- PLOD2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PNPLA7 | c.2807+2T>C p.X936_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- PRDM12 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT8 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- PSD3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- PTPN1 | c.1228del p.L410Wfs*49 | Frame Shift Del (DEL) | VAF 27/185 reads (15%) | called by mutect2, pindel, varscan2
- RC3H2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RP1L1 | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 50/385 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RPL3L | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RSAD2 | c.413A>T p.K138M | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); called by muse, mutect2
- RSF1 | c.1131C>A p.D377E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- RTP5 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- SESN2 | c.1339T>G p.F447V | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC22A25 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A2 | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 94/169 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- SLC35G5 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 200/635 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9C2 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SNCA | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 14/263 reads (5%) | called by muse, mutect2
- SRP68 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- STXBP5 | c.1700C>A p.T567K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- TBL1X | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 85/88 reads (97%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TGFBR2 | c.871_873del p.K291del | In Frame Del (DEL) | VAF 163/173 reads (94%) | called by mutect2, pindel, varscan2
- TIMM23B | c.261G>T p.G87= | Splice Region (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- TRIB1 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2
- TRIM46 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TUBGCP6 | c.1836_1839del p.Y613Sfs*13 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- USP29 | c.1925A>T p.E642V | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); called by muse, mutect2
- WBP2 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- XIRP2 | c.1393G>T p.A465S (on ENST00000628543; = p.A640S on NM_152381.6) | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ZNF211 | c.1562G>C p.S521T (on ENST00000347302 / NM_198855.4; = p.S534T on NM_006385.5) | Missense Mutation (SNP) | VAF 293/434 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF334 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF419 | c.199+4A>T | Splice Region (SNP) | VAF 21/734 reads (3%) | called by muse, mutect2
- ZNF570 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 19/465 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- ZNF577 | c.1095C>A p.H365Q | Missense Mutation (SNP) | VAF 112/727 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF582 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZYG11B | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY8 | c.1962T>C p.L654= | Silent (SNP) | VAF 16/580 reads (3%) | catalogued as COSV53911124; called by muse, mutect2
- C10orf53 | c.54C>G p.G18= | Silent (SNP) | VAF 177/398 reads (44%) | called by muse, mutect2, varscan2
- C2CD4C | c.543C>T p.A181= | Silent (SNP) | VAF 62/62 reads (100%) | catalogued as rs763016255; called by muse, mutect2, varscan2
- CCNL2 | c.114G>A p.G38= | Silent (SNP) | VAF 21/248 reads (8%) | catalogued as rs961630724, COSV100784970, COSV61224734; called by muse, mutect2
- CTNNA2 | c.1126C>T p.L376= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV58169980; called by muse, mutect2, varscan2
- DNAH10 | c.459G>A p.E153= (on ENST00000409039; = p.E92= on NM_207437.3) | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1473158162, COSV68990507; called by muse, mutect2, varscan2
- FAM163A | c.30C>T p.G10= | Silent (SNP) | VAF 132/133 reads (99%) | catalogued as rs1489128839, COSV59203194; called by muse, mutect2, varscan2
- FAM71E2 | c.433C>T p.L145= | Silent (SNP) | VAF 60/366 reads (16%) | called by muse, mutect2, varscan2
- H2BW1 | c.24G>A p.R8= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as rs781903431; called by muse, mutect2
- HBS1L | c.918G>C p.S306= | Silent (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- HTR1E | c.195C>T p.A65= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs200678632; called by muse, mutect2, varscan2
- IGLL1 | c.468C>T p.I156= | Silent (SNP) | VAF 316/681 reads (46%) | called by muse, mutect2, varscan2
- IL21R | c.63C>A p.P21= | Silent (SNP) | VAF 74/136 reads (54%) | catalogued as COSV61971732; called by muse, mutect2, varscan2
- ITGA2B | c.2367C>T p.S789= | Silent (SNP) | VAF 14/226 reads (6%) | catalogued as rs761819126; called by muse, mutect2
- KBTBD3 | c.738A>G p.L246= | Silent (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- KCTD7 | c.90G>A p.P30= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- LRP3 | c.2298C>T p.A766= | Silent (SNP) | VAF 121/417 reads (29%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.1359C>A p.A453= | Silent (SNP) | VAF 24/118 reads (20%) | called by mutect2, varscan2
- MCC | c.144C>T p.D48= | Silent (SNP) | VAF 98/100 reads (98%) | called by muse, mutect2
- MYCN | c.363C>T p.S121= | Silent (SNP) | VAF 40/137 reads (29%) | called by muse, mutect2, varscan2
- NEUROD2 | c.342G>A p.A114= | Silent (SNP) | VAF 153/288 reads (53%) | catalogued as COSV100223240; called by muse, varscan2
- NF1 | c.2934C>T p.G978= | Silent (SNP) | VAF 74/148 reads (50%) | called by muse, mutect2, varscan2
- NID1 | c.1021A>C p.R341= | Silent (SNP) | VAF 196/196 reads (100%) | called by muse, mutect2, varscan2
- NOMO3 | c.636C>T p.L212= | Silent (SNP) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- OR4Q3 | c.159A>T p.I53= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV59180235; called by muse, mutect2
- PAX1 | c.588C>A p.I196= | Silent (SNP) | VAF 94/601 reads (16%) | catalogued as rs751544378, COSV68273593; called by muse, varscan2
- POF1B | c.234C>G p.L78= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs1274393275, COSV99427182; called by muse, mutect2, varscan2
- PTPRQ | c.1062C>T p.C354= (on ENST00000616559; = p.C312= on NM_001145026.2) | Silent (SNP) | VAF 73/125 reads (58%) | catalogued as rs1161794835, COSV99883285; called by muse, mutect2, varscan2
- RBM12 | c.2484C>G p.G828= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs1277679217; called by muse, mutect2, varscan2
- REM2 | c.121C>T p.L41= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2
- RIMS1 | c.66G>T p.L22= | Silent (SNP) | VAF 122/123 reads (99%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.991T>C p.L331= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs746770989; called by muse, mutect2, varscan2
- SCARF2 | c.2295G>A p.P765= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1431657904; called by muse, mutect2, varscan2
- SEMA6C | c.2355G>A p.E785= | Silent (SNP) | VAF 100/102 reads (98%) | called by muse, mutect2, varscan2
- SERPING1 | c.834A>G p.L278= | Silent (SNP) | VAF 44/525 reads (8%) | called by muse, mutect2
- SHISA7 | c.402G>A p.P134= | Silent (SNP) | VAF 78/472 reads (17%) | catalogued as rs1207115618; called by muse, mutect2, varscan2
- SIN3A | c.1596T>G p.T532= | Silent (SNP) | VAF 27/326 reads (8%) | catalogued as rs1404897354; called by muse, mutect2
- SOX11 | c.1224C>T p.G408= | Silent (SNP) | VAF 163/332 reads (49%) | catalogued as rs1489617288; called by muse, mutect2, varscan2
- SYNPO2L | c.1149C>G p.V383= (on ENST00000394810 / NM_001114133.3; = p.V159= on NM_024875.5) | Silent (SNP) | VAF 9/252 reads (4%) | catalogued as rs960623861; called by muse, mutect2
- TBL1XR1 | c.42A>G p.R14= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs1304650453; called by muse, mutect2
- TECPR2 | c.150G>A p.V50= | Silent (SNP) | VAF 48/228 reads (21%) | catalogued as rs372796531; called by muse, mutect2, varscan2
- TENM3 | c.1980A>G p.Q660= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as rs951655096; called by muse, mutect2, varscan2
- TMEM59L | c.834G>T p.V278= | Silent (SNP) | VAF 160/162 reads (99%) | called by muse, mutect2, varscan2
- TRPM8 | c.6C>T p.S2= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV100223900; called by muse, mutect2
- TTN | c.7893A>T p.V2631= (on ENST00000591111; = p.V2585= on NM_003319.4) | Silent (SNP) | VAF 36/290 reads (12%) | called by muse, mutect2, varscan2
- USP17L7 | c.234G>T p.V78= | Silent (SNP) | VAF 262/1381 reads (19%) | catalogued as rs1280243121; called by muse, mutect2, varscan2
- WNK3 | c.3762C>T p.S1254= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- AC073621.1 | n.379G>T | RNA (SNP) | VAF 137/139 reads (99%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849787 G>T | 5'Flank (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849788 A>T | 5'Flank (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- ANAPC1P4 | n.1071G>A | RNA (SNP) | VAF 98/341 reads (29%) | catalogued as rs764294257; called by muse, mutect2, varscan2
- APOBEC3B | c.*40T>G | 3'UTR (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- C5orf17 | n.348G>A | RNA (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- CAPS2 | c.1670-2731A>C | Intron (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.871-15G>T | Intron (SNP) | VAF 62/144 reads (43%) | called by muse, mutect2, varscan2
- EPB42 | c.-23G>A | 5'UTR (SNP) | VAF 16/425 reads (4%) | called by muse, mutect2
- FER1L4 | n.4454C>T | RNA (SNP) | VAF 77/483 reads (16%) | catalogued as rs529333181; called by muse, mutect2, varscan2
- HLA-DQA1 | c.614-13T>G | Intron (SNP) | VAF 30/441 reads (7%) | called by muse, mutect2
- IGFN1 | c.1241+1444C>T | Intron (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2
- IL16 | c.-176G>T | 5'UTR (SNP) | VAF 143/232 reads (62%) | called by muse, mutect2, varscan2
- ITGAL | c.165-13G>A | Intron (SNP) | VAF 30/68 reads (44%) | called by mutect2, varscan2
- KRTAP21-3 | c.*1G>T | 3'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- L2HGDH | chr14:50237705 G>A | 3'Flank (SNP) | VAF 46/46 reads (100%) | catalogued as rs756741363, COSV99910470; called by muse, mutect2, varscan2
- LINC01804 | n.417C>T | RNA (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- MEIOC | c.-47G>A | 5'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs1353407802; called by muse, mutect2
- PLEKHM1 | c.*1490A>T | 3'UTR (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- PPM1M | chr3:52245858 C>A | 5'Flank (SNP) | VAF 9/43 reads (21%) | catalogued as rs1411643986; called by muse, mutect2, varscan2
- PPP4R1L | n.1574C>A | RNA (SNP) | VAF 87/252 reads (35%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1223C>T | RNA (SNP) | VAF 80/82 reads (98%) | called by muse, mutect2, varscan2
- ROBO2 | c.3136+551A>G | Intron (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- SSPOP | n.14495G>A | RNA (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- TNS1 | c.-155A>G | 5'UTR (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- TSGA13 | c.-16C>T | 5'UTR (SNP) | VAF 70/70 reads (100%) | called by muse, mutect2, varscan2
- ULK4P2 | n.223G>A | RNA (SNP) | VAF 64/408 reads (16%) | called by muse, mutect2
- WDR36 | c.-19G>A | 5'UTR (SNP) | VAF 10/98 reads (10%) | catalogued as rs1355865661; called by muse, mutect2
- ZNF320 | c.-36A>C | 5'UTR (SNP) | VAF 11/201 reads (5%) | called by muse, mutect2
